TCGA case TCGA-WB-A814 — Pheochromocytoma and Paraganglioma (TCGA-PCPG)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Paragangliomas and Glomus Tumors; Primary site: Retroperitoneum and peritoneum; Tissue source site: Erasmus MC. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/5a92887a-c367-4fa7-a696-23e70de033c7

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Country of residence at enrollment: France; Age at index: 35 years; Vital status: Alive.

Diagnoses (3)
1. Extra-adrenal paraganglioma, malignant (the primary disease): ICD-O-3 morphology code: 8693/3; ICD-10 code: C48.0; Tissue or organ of origin: Retroperitoneum; Site of resection or biopsy: Retroperitoneum; Classification of tumor: primary; Age at diagnosis: 35.4 years (12,936 days); Year of diagnosis: 2008; Prior malignancy: no; Synchronous malignancy: Yes; Prior treatment: No; Days to last follow up: 2,252 days (6.2 years); Cancer detection method: Screening.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 1; Lymph nodes tested: 1.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Paraganglioma, NOS: ICD-O-3 morphology code: 8680/1; Tissue or organ of origin: Lymph node, NOS; Classification of tumor: Synchronous primary; Age at diagnosis: 35.4 years (12,936 days).
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: -49 days.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
3. Pheochromocytoma, NOS: ICD-O-3 morphology code: 8700/0; Tissue or organ of origin: Adrenal gland, NOS; Laterality: Right; Classification of tumor: Synchronous primary; Age at diagnosis: 35.4 years (12,936 days).
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: -49 days.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.

Follow-up (3 entries)
- Day 0 (prior to diagnosis): History of tumor: Yes; History of tumor type: Phenochromocytoma or Paraganglioma.
- Days to follow up: 1,000 days (2.7 years); Disease response: Tumor Free.
- Days to follow up: 2,252 days (6.2 years); Disease response: Tumor Free.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-WB-A814-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 140 mg.
  Slide TCGA-WB-A814-01A-01-TSA: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 30; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-WB-A814-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-WB-A814-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History pheo or para include benign: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.
- Primary pathology: Submitted tumor site: Extra-adrenal Site; Site of primary tumor other: para-aortic/pericaval; Related tumors outside adrenal glands: Single tumor outside the adrenal glands; Histologic diagnosis: Paraganglioma, Extra-adrenal Pheochromocytoma; Disease detected on screening: Yes; Ct scan preop results: Yes; Lymph nodes examined: Yes.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Other malignancy form 1: Malignancy type: Synchronous Malignancy; Other malignancy anatomic site: adrenal gland; Other malignancy histological type: pheochromocytoma.
- Other malignancy form 1, Surgery: Other malignancy surgery type: surgery.
- Other malignancy form 2: Malignancy type: Synchronous Malignancy; Other malignancy anatomic site: inter-aortico-caval lymph node; Other malignancy histological type: paraganglioma.
- Other malignancy form 2, Surgery: Other malignancy surgery type: surgical resection.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 2,252 days; disease-specific survival: no event (censored), 2,252 days; disease-free interval: no event (censored), 2,252 days; progression-free interval: no event (censored), 2,252 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-WB-A814-01A-11D-A35H-01): tumor purity 0.58, ploidy 1.9, whole-genome doublings 0.
